Somatic mutation profile of tumor specimen 0DD874 from CCDI case PBBNII, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Genital rhabdomyoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.0 years (5,489 days).
Specimen 0DD874: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c799e83-de3f-4e6a-b6c2-50ff65a4a4ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD86Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2450841e-6b97-4cbe-9365-dbd02895b6d1

The open-access MAF lists 163 somatic variants for this specimen: 105 protein-altering or splice-affecting, 32 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 32, Intron 16, Nonsense Mutation 5, 3'UTR 4, Splice Site 3, Splice Region 3, 5'Flank 2, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 935/1695 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.1454G>A p.R485H (on ENST00000326724 / NM_001080395.3; = p.R382H on NM_004920.2) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as rs1174069471, COSV58687933; called by muse, mutect2, varscan2
- ACSS2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 74/878 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs758227933, COSV53624851; called by muse, mutect2
- ACTR10 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as rs1210554461; called by mutect2, varscan2
- ADAMTSL1 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 257/393 reads (65%) | catalogued as rs751209198; called by muse, mutect2, varscan2
- AKAP3 | c.1547T>G p.F516C | Missense Mutation (SNP) | VAF 86/652 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV99961869; called by muse, mutect2, varscan2
- APOBEC4 | c.432del p.Y145Ifs*42 | Frame Shift Del (DEL) | VAF 136/933 reads (15%) | catalogued as COSV100426148; called by mutect2, varscan2
- ATP2C1 | c.1893G>A p.S631= | Splice Region (SNP) | VAF 57/962 reads (6%) | catalogued as rs757607522; called by muse, mutect2
- ATRX | c.2429C>G p.T810S | Missense Mutation (SNP) | VAF 151/439 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100971266; called by muse, mutect2, varscan2
- CACNA1H | c.4837C>A p.L1613M | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.418); catalogued as rs1183322366, COSV61989433; called by muse, mutect2
- CFAP299 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 88/712 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs751823292; called by muse, mutect2, varscan2
- CTSV | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 124/677 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs754510545, COSV99414458; called by muse, mutect2, varscan2
- DOCK3 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as rs758629699, COSV99809766; called by muse, mutect2, varscan2
- EPHB6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 98/771 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67418031; called by muse, mutect2, varscan2
- FCRL4 | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 198/1386 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99620264; called by muse, mutect2, varscan2
- FOXA3 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762659076, COSV56216227; called by muse, mutect2, varscan2
- GALNT17 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.108); catalogued as rs751442349, COSV61156187, COSV61184393; called by muse, mutect2
- GYS1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs1338075033, COSV54401846, COSV99621061; called by muse, mutect2
- HHLA1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 76/449 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs756674684; called by muse, mutect2, varscan2
- HSP90AA1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 63/335 reads (19%) | PolyPhen benign (0); catalogued as rs745392407; called by muse, mutect2, varscan2
- KCND2 | c.1009A>G p.I337V | Missense Mutation (SNP) | VAF 63/564 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs1412701135; called by muse, mutect2, varscan2
- KCNH7 | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 162/1590 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV59792008; called by muse, mutect2
- KIF26A | c.353G>C p.R118P | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.654); catalogued as COSV59467966; called by muse, varscan2
- KIRREL3 | c.1310A>G p.Q437R | Missense Mutation (SNP) | VAF 72/631 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as rs1213515537; called by muse, mutect2, varscan2
- LRCH1 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 83/1076 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs776940514; called by muse, mutect2
- MGAM | c.3278G>A p.G1093E | Missense Mutation (SNP) | VAF 28/1008 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779664504, COSV101527796; called by muse, mutect2
- MIER2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53397290; called by muse, mutect2
- NACA2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 214/1056 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs765470743, COSV71713090; called by muse, mutect2, varscan2
- NRIP1 | c.3341C>T p.T1114M | Missense Mutation (SNP) | VAF 164/1045 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs755574891, COSV59660419; called by muse, mutect2, varscan2
- OR5I1 | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 184/940 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV56888427; called by muse, mutect2, varscan2
- OSR2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 144/606 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs763588260, COSV99882751; called by muse, varscan2
- PLXNB1 | c.5778G>C p.K1926N | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602929; called by muse, mutect2
- PON2 | c.605C>A p.A202E | Missense Mutation (SNP) | VAF 329/1372 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1271180200, COSV56000358, COSV56001161; called by muse, mutect2, varscan2
- PSME4 | c.5343G>T p.M1781I | Missense Mutation (SNP) | VAF 124/987 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV66363772; called by muse, mutect2, varscan2
- PXDN | c.2662G>A p.G888S | Missense Mutation (SNP) | VAF 147/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404843853; called by muse, mutect2, varscan2
- RAB11B | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV60085428; called by muse, mutect2, varscan2
- RGR | c.370+1G>A p.X124_splice | Splice Site (SNP) | VAF 83/616 reads (13%) | catalogued as rs548051515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.4015G>T p.V1339F | Missense Mutation (SNP) | VAF 62/747 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs763095202, COSV51663715; called by muse, mutect2
- SDK1 | c.6533C>T p.A2178V | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs746870660, COSV67357331; called by muse, mutect2, varscan2
- SLC2A7 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs769352024, COSV68901634; called by muse, mutect2, varscan2
- SLC39A12 | c.462A>C p.E154D | Missense Mutation (SNP) | VAF 154/965 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV101069928; called by muse, mutect2, varscan2
- SORL1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 135/1629 reads (8%) | catalogued as rs1292268635; called by muse, mutect2
- SUCLG2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 135/661 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as rs753617532; called by muse, mutect2, varscan2
- TBC1D9B | c.2987C>T p.P996L (on ENST00000356834 / NM_198868.3; = p.P979L on NM_015043.4) | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs1356180868, COSV62282689; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 38/405 reads (9%) | catalogued as rs754083634; called by mutect2, varscan2
- UTP14C | c.1821C>A p.F607L | Missense Mutation (SNP) | VAF 125/1161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV73000645; called by muse, mutect2, varscan2
- WFIKKN1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs766108080; called by muse, mutect2, varscan2
- ABHD16B | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ADIPOQ | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 129/540 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP1AR | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 146/674 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3B2 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- BBX | c.1494G>T p.W498C | Missense Mutation (SNP) | VAF 44/1078 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMP3 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 128/741 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD10 | c.1108G>T p.G370* | Nonsense Mutation (SNP) | VAF 118/730 reads (16%) | called by muse, mutect2, varscan2
- C4A | c.2627G>A p.C876Y | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCK | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2
- CDH26 | c.2155C>A p.L719M (on ENST00000348616 / NM_177980.4; = p.L52M on NM_021810.6) | Missense Mutation (SNP) | VAF 116/864 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CHMP4B | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 76/588 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- COL5A2 | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 82/716 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CRACDL | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 140/709 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CRACR2A | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 55/464 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CROCC2 | c.3215G>T p.R1072L | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by mutect2, varscan2
- CTNNA2 | c.2357G>T p.C786F | Missense Mutation (SNP) | VAF 192/1530 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAGLA | c.3049G>T p.D1017Y | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2
- DDX47 | c.125T>C p.L42S | Missense Mutation (SNP) | VAF 134/1058 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- DIRAS3 | c.-65-1G>T | Splice Site (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- DUS3L | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2
- FNDC4 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KMT2D | c.10749del p.K3583Nfs*75 | Frame Shift Del (DEL) | VAF 32/223 reads (14%) | called by mutect2, varscan2
- MGAM2 | c.4504G>T p.G1502* | Nonsense Mutation (SNP) | VAF 179/833 reads (21%) | called by muse, mutect2, varscan2
- MORC2 | c.1757C>T p.S586F (on ENST00000397641 / NM_001303256.3; = p.S524F on NM_014941.3) | Missense Mutation (SNP) | VAF 30/802 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC12 | c.3790A>G p.T1264A (on ENST00000379442; = p.T1121A on NM_001164462.1) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- NARF | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NCK1 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 99/931 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOXO1 | c.602-3C>T | Splice Region (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- NPAT | c.3072-2A>G p.X1024_splice | Splice Site (SNP) | VAF 76/802 reads (9%) | called by muse, mutect2
- NUP210 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 77/658 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR56A5 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 104/864 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDAP1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 77/526 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDE4DIP | c.4262C>A p.S1421Y | Missense Mutation (SNP) | VAF 79/1142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDE4DIP | c.5229G>T p.Q1743H | Missense Mutation (SNP) | VAF 126/1294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGBD1 | c.1884C>A p.S628R | Missense Mutation (SNP) | VAF 234/599 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- POLR2A | c.2508C>A p.F836L | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- POLR2B | c.2182A>G p.M728V | Missense Mutation (SNP) | VAF 74/608 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG5 | c.227A>C p.Y76S | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RIMS1 | c.2216C>A p.P739Q | Missense Mutation (SNP) | VAF 343/1042 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RINT1 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 122/813 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SCN10A | c.3260G>T p.S1087I | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN8A | c.3243G>T p.E1081D | Missense Mutation (SNP) | VAF 145/426 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SERPINB4 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 127/652 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SF3B3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 226/712 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SHANK1 | c.4219C>T p.L1407F | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2
- SHCBP1 | c.1464G>A p.K488= | Splice Region (SNP) | VAF 30/532 reads (6%) | called by muse, mutect2
- SLC14A2 | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 111/617 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC24A1 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC35F4 | c.526T>C p.S176P (on ENST00000339762 / NM_001352015.2; = p.S140P on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/529 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLPI | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 80/662 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX6 | c.1510C>G p.R504G (on ENST00000528429 / NM_001145819.2; = p.R477G on NM_017508.3) | Missense Mutation (SNP) | VAF 126/1114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRIM42 | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 114/673 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRUB1 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 83/465 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.90457G>A p.V30153I (on ENST00000591111; = p.V22729I on NM_003319.4) | Missense Mutation (SNP) | VAF 135/988 reads (14%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.40933G>A p.G13645S (on ENST00000591111; = p.G6221S on NM_003319.4) | Missense Mutation (SNP) | VAF 91/1421 reads (6%) | PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNF165 | c.1381T>A p.C461S | Missense Mutation (SNP) | VAF 414/746 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF233 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 96/678 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF627 | c.501T>G p.Y167* | Nonsense Mutation (SNP) | VAF 74/551 reads (13%) | called by muse, mutect2, varscan2
- ACADL | c.1086C>T p.S362= | Silent (SNP) | VAF 144/1255 reads (11%) | catalogued as rs149023402; called by muse, mutect2, varscan2
- AGBL1 | c.834C>T p.A278= | Silent (SNP) | VAF 92/466 reads (20%) | called by muse, mutect2, varscan2
- C5orf51 | c.666G>A p.S222= | Silent (SNP) | VAF 195/1276 reads (15%) | catalogued as rs550639235; called by muse, mutect2, varscan2
- CEP170 | c.57A>T p.P19= | Silent (SNP) | VAF 214/1949 reads (11%) | called by muse, mutect2, varscan2
- CLPB | c.501C>T p.G167= | Silent (SNP) | VAF 123/968 reads (13%) | called by muse, mutect2, varscan2
- DMBT1 | c.2119C>A p.R707= | Silent (SNP) | VAF 50/660 reads (8%) | called by muse, mutect2
- DUSP29 | c.348G>T p.L116= | Silent (SNP) | VAF 45/295 reads (15%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2952C>A p.T984= | Silent (SNP) | VAF 104/644 reads (16%) | called by muse, mutect2, varscan2
- HERC5 | c.1878C>T p.C626= | Silent (SNP) | VAF 125/776 reads (16%) | catalogued as rs111323592, COSV52046834; called by muse, mutect2, varscan2
- MAP1A | c.3168C>T p.G1056= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- MGAT3 | c.1320C>T p.F440= | Silent (SNP) | VAF 57/464 reads (12%) | catalogued as COSV100361808, COSV57868514; called by muse, mutect2, varscan2
- MRGPRF | c.207C>T p.F69= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as rs759161378; called by muse, mutect2
- NOS2 | c.3120G>A p.A1040= | Silent (SNP) | VAF 36/215 reads (17%) | called by muse, mutect2, varscan2
- OR10H5 | c.540C>T p.H180= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs766446873, COSV58278521; called by muse, mutect2, varscan2
- OR4C45 | c.567T>G p.T189= | Silent (SNP) | VAF 76/695 reads (11%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1944G>T p.L648= | Silent (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.702C>T p.D234= | Silent (SNP) | VAF 115/628 reads (18%) | catalogued as rs774355733, COSV53953465; called by muse, mutect2, varscan2
- PENK | c.564C>A p.G188= | Silent (SNP) | VAF 168/720 reads (23%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2487C>T p.N829= | Silent (SNP) | VAF 116/1380 reads (8%) | called by muse, mutect2
- RAPGEF4 | c.1869G>T p.L623= | Silent (SNP) | VAF 173/1125 reads (15%) | called by muse, mutect2, varscan2
- RLIM | c.606C>T p.V202= | Silent (SNP) | VAF 142/349 reads (41%) | catalogued as rs1452967575, COSV100223364; called by muse, mutect2, varscan2
- SCN1A | c.4866C>T p.A1622= (on ENST00000303395 / NM_001202435.3; = p.A1611= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/764 reads (19%) | catalogued as rs763877632, COSV100320290; called by muse, mutect2, varscan2
- SERPINA9 | c.507C>A p.S169= | Silent (SNP) | VAF 104/522 reads (20%) | called by muse, mutect2, varscan2
- SLC44A2 | c.1380G>T p.V460= | Silent (SNP) | VAF 78/294 reads (27%) | called by muse, mutect2, varscan2
- SLC5A9 | c.1014C>T p.I338= | Silent (SNP) | VAF 40/335 reads (12%) | catalogued as rs1323310121, COSV52582589; called by muse, mutect2, varscan2
- SPG11 | c.1755A>G p.P585= | Silent (SNP) | VAF 114/492 reads (23%) | called by muse, mutect2, varscan2
- TAS2R31 | c.858A>C p.L286= | Silent (SNP) | VAF 380/1593 reads (24%) | called by muse, varscan2
- TRPM4 | c.2709G>C p.T903= | Silent (SNP) | VAF 97/818 reads (12%) | called by muse, mutect2, varscan2
- TUBA3C | c.930C>A p.G310= | Silent (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- WDR97 | c.1266C>T p.P422= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as rs956720455; called by muse, mutect2, varscan2
- ZNF835 | c.1593G>A p.P531= | Silent (SNP) | VAF 72/671 reads (11%) | catalogued as rs766981930, COSV101606331; called by muse, mutect2, varscan2
- ZNF880 | c.1050A>G p.K350= | Silent (SNP) | VAF 134/865 reads (15%) | called by muse, mutect2, varscan2
- ADAM7 | c.-26G>T | 5'UTR (SNP) | VAF 133/812 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.941-11C>A | Intron (SNP) | VAF 263/529 reads (50%) | called by muse, mutect2, varscan2
- CHD8 | c.1968+12T>C | Intron (SNP) | VAF 71/437 reads (16%) | called by muse, mutect2, varscan2
- CHMP5 | chr9:33265026 G>A | 5'Flank (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- EEF1B2 | c.-21-63C>A | Intron (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- EFNB2 | c.614-100G>T | Intron (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2
- EIF4A3 | c.728+64G>C | Intron (SNP) | VAF 40/222 reads (18%) | called by muse, varscan2
- EYS | c.1767-7295G>T | Intron (SNP) | VAF 35/1030 reads (3%) | called by muse, mutect2
- GJC2 | c.*17G>T | 3'UTR (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- IRF9 | c.992-26C>A | Intron (SNP) | VAF 16/121 reads (13%) | called by muse, varscan2
- LMAN1L | c.330+23G>T | Intron (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2
- LRP4 | c.5244-34C>A | Intron (SNP) | VAF 39/342 reads (11%) | called by muse, mutect2, varscan2
- LRRK2 | c.7462+80G>T | Intron (SNP) | VAF 32/443 reads (7%) | called by muse, mutect2
- MARVELD3 | chr16:71641074 G>T | 3'Flank (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- MEIKIN | c.201-17C>T | Intron (SNP) | VAF 89/659 reads (14%) | called by muse, mutect2, varscan2
- MYCL | chr1:39901935 del G | 5'Flank (DEL) | VAF 4/28 reads (14%) | catalogued as rs1259820174, COSV65693292; called by mutect2, varscan2
- NFKB1 | c.569-35C>T | Intron (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2
- ODF3 | c.-8-72G>A | Intron (SNP) | VAF 3/19 reads (16%) | catalogued as rs1264015705; called by muse, mutect2
- OR1D4 | n.384C>T | RNA (SNP) | VAF 82/229 reads (36%) | catalogued as rs1290211672; called by muse, mutect2, varscan2
- PSMC4 | c.1088-61G>T | Intron (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2
- SEMA6D | c.-51G>T | 5'UTR (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- SMIM35 | c.*1896T>C | 3'UTR (SNP) | VAF 51/524 reads (10%) | called by muse, mutect2, varscan2
- UCK2 | c.259+93G>T | Intron (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- WDR72 | c.*97C>A | 3'UTR (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
- ZDHHC1 | c.*132C>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ZNF32 | c.70+42A>G | Intron (SNP) | VAF 95/739 reads (13%) | called by muse, mutect2, varscan2
